Somatic mutation profile of tumor specimen TCGA-BP-5181-01A (aliquot TCGA-BP-5181-01A-01D-1429-08) from TCGA case TCGA-BP-5181, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.9 years (21,514 days).
Specimen TCGA-BP-5181-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 690281ee-5001-47fa-8739-84fd5da630fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5181-11A (Solid Tissue Normal), aliquot TCGA-BP-5181-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2be0515d-699b-43b8-b6a2-e51f8050d4e3

The open-access MAF lists 55 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 10, Frame Shift Del 3, Nonsense Mutation 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAMDC | c.31T>C p.W11R | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59020483; called by muse, mutect2, varscan2
- ACADS | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV54370024; called by muse, mutect2, varscan2
- ANKRD20A2P | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV66464865; called by muse, mutect2
- ARL6IP6 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 99/282 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58443892; called by muse, mutect2, varscan2
- C16orf78 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs371310295; called by muse, mutect2, varscan2
- CCDC102A | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV50778749; called by muse, varscan2
- CD44 | c.221T>A p.F74Y | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV53535986; called by muse, mutect2, varscan2
- CNTN5 | c.2423G>A p.G808D | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54345800; called by muse, mutect2, varscan2
- DDX21 | c.2313A>T p.K771N | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV62556481; called by muse, mutect2, varscan2
- DHRS7B | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV60888437; called by muse, mutect2, varscan2
- DIP2B | c.1296A>G p.I432M | Missense Mutation (SNP) | VAF 102/287 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56590081; called by muse, mutect2, varscan2
- DNMT3A | c.868T>A p.F290I | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV53071386; called by muse, mutect2, varscan2
- FBXO39 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV58621074; called by muse, mutect2, varscan2
- G3BP1 | c.58T>C p.Y20H | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62366790; called by muse, mutect2, varscan2
- GSAP | c.2074T>G p.L692V | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV57532510; called by muse, mutect2, varscan2
- HNRNPU | c.1178C>G p.T393S (on ENST00000283179; = p.T455S on NM_004501.3) | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); catalogued as COSV51693494; called by muse, mutect2, varscan2
- IRX1 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57359430; called by muse, mutect2, varscan2
- KAT6A | c.5333C>A p.T1778N | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55910901; called by muse, mutect2, varscan2
- KL | c.2488G>A p.V830M | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101199133; called by muse, mutect2, varscan2
- KL | c.2489T>A p.V830E | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101199135; called by muse, mutect2, varscan2
- MICAL2 | c.1910G>T p.G637V | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV56324060, COSV56324786; called by muse, mutect2, varscan2
- NPHP3 | c.1039A>T p.N347Y | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.161); catalogued as COSV58130500; called by muse, mutect2, varscan2
- PBLD | c.747A>C p.E249D | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV53267039; called by muse, mutect2, varscan2
- PBRM1 | c.139-1G>T p.X47_splice | Splice Site (SNP) | VAF 43/83 reads (52%) | catalogued as COSV99967981, COSV99969669; called by muse, mutect2, varscan2
- PCNT | c.2022A>T p.E674D | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV64031966; called by muse, mutect2, varscan2
- POU5F1 | c.335C>G p.P112R | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.32); catalogued as COSV52564715, COSV99462974; called by muse, mutect2, varscan2
- PRKAG1 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV60294228; called by muse, varscan2
- RAB8A | c.521A>T p.D174V | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV53739287; called by muse, mutect2
- SCN9A | c.3937G>A p.A1313T (on ENST00000303354; = p.A1302T on NM_002977.3) | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57620684; called by muse, mutect2, varscan2
- SIPA1L3 | c.3466C>A p.Q1156K | Missense Mutation (SNP) | VAF 158/541 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.024); catalogued as COSV55922038; called by muse, mutect2, varscan2
- SLC28A3 | c.1556A>C p.E519A | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66154591; called by muse, mutect2, varscan2
- SREBF2 | c.2617A>G p.I873V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375253567; called by muse, mutect2, varscan2
- TCF20 | c.5480C>A p.S1827Y | Missense Mutation (SNP) | VAF 114/325 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV59489719, COSV59495069; called by muse, mutect2, varscan2
- TRIM73 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554467455, COSV99303088; called by muse, mutect2, varscan2
- TRMT9B | c.965A>G p.E322G | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs764700281, COSV71600585; called by muse, mutect2, varscan2
- TSC2 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54775966; called by muse, mutect2, varscan2
- UBQLN1 | c.1022C>A p.T341N | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.055); catalogued as COSV57409014; called by muse, mutect2, varscan2
- UNC79 | c.2333A>C p.N778T (on ENST00000393151 / NM_001346218.2; = p.N601T on NM_020818.5) | Missense Mutation (SNP) | VAF 117/379 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV56405156; called by muse, mutect2, varscan2
- VHL | c.274_278del p.D92Rfs*38 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as COSV56560956; called by mutect2, varscan2
- VKORC1 | c.223A>C p.I75L | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV54926154; called by muse, mutect2, varscan2
- ZHX2 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.419); catalogued as COSV58716069; called by muse, mutect2, varscan2
- CHPT1 | c.972del p.Q325Kfs*13 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | called by mutect2, pindel, varscan2
- LRG1 | c.917_920del p.N306Rfs*29 | Frame Shift Del (DEL) | VAF 41/140 reads (29%) | called by mutect2, pindel, varscan2
- NID1 | c.1382dup p.Y461* | Nonsense Mutation (INS) | VAF 26/116 reads (22%) | called by mutect2, pindel, varscan2
- CEP85 | c.1089G>A p.L363= | Silent (SNP) | VAF 44/158 reads (28%) | catalogued as COSV53331940, COSV53332649; called by muse, mutect2, varscan2
- DMRTB1 | c.123C>T p.Y41= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV65113778; called by muse, mutect2
- LMBR1L | c.1062C>A p.V354= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV57268773; called by muse, mutect2, varscan2
- MLLT1 | c.1233C>G p.S411= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV53130776, COSV53132584, COSV99397974; called by muse, mutect2
- MTSS1 | c.216C>A p.T72= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV61499360; called by muse, mutect2, varscan2
- MUC5AC | c.1191C>T p.V397= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV62255158; called by muse, mutect2, varscan2
- NAGPA | c.609G>T p.V203= | Silent (SNP) | VAF 104/288 reads (36%) | catalogued as rs138461608; called by muse, mutect2, varscan2
- PICALM | c.405A>G p.A135= | Silent (SNP) | VAF 85/252 reads (34%) | catalogued as COSV62673252; called by muse, mutect2, varscan2
- SLC5A10 | c.1053C>T p.I351= (on ENST00000395645 / NM_001042450.4; = p.I367= on NM_152351.5) | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs758808400, COSV58758623; called by muse, mutect2, varscan2
- ZBTB11 | c.1926T>A p.S642= | Silent (SNP) | VAF 59/178 reads (33%) | catalogued as COSV57246505; called by muse, mutect2, varscan2
- PRDM15 | c.-104T>C | 5'UTR (SNP) | VAF 55/158 reads (35%) | catalogued as COSV54158196; called by muse, mutect2, varscan2
